Surgical pathology report (de-identified scan), TCGA case TCGA-B0-4841, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-B0-4841-01A (Primary Tumor).

FINAL DIAGNOSIS

LEFT KIDNEY, RADICAL NEPHRECTOMY –

- A. RENAL CELL CARCINOMA, CONVENTIONAL (CLEAR CELL) TYPE, FUHRMAN'S NUCLEAR GRADE 3 OF 4.
- B. THE TUMOR IS 7.5 cm IN GREATEST DIMENSION.
- C. A 3.5 cm SATELLITE FOCUS OF RENAL CELL CARCINOMA IS IDENTIFIED, THIS FOCUS IS OF CONVENTIONAL TYPE, FUHRMAN'S NUCLEAR GRADE 3 OF 4.
- D. THE TWO FOCI OF RENAL CELL CARCINOMA ARE CONFINED TO THE KIDNEY, WITH NO INVASION INTO THE PERINEPHRIC OR HILAR ADIPOSE TISSUE.
- E. ALL SURGICAL MARGINS ARE FREE OF NEOPLASIA.
- F. ADRENAL GLAND WITH RECENT HEMATOMA AND NO SIGNIFICANT PATHOLOGIC FINDINGS (see comment).
- G. PATHOLOGIC TNM STAGING: pT2 Nx Mx.

Source: NCI Genomic Data Commons file 5f2d19a3-e212-489e-9ca5-0a18f378cf33 (TCGA-B0-4841.CA4F8F54-A032-44C6-8EFE-87B8C5B6E03B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).